CCDI case PBCTUD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6cef6415-912d-4848-808f-796a1cde54e7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 21.1 years (7,703 days).

Biospecimens (3 samples)
- Sample 0DZEGP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZEH1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZEHP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
